Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5681, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5681-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

(A) LEFT KIDNEY, ADRENAL WITH RENAL VEIN THROMBUS:

KIDNEY:

FUHRMAN NUCLEAR GRADE 3 RENAL CELL CARCINOMA - CONVENTIONAL (CLEAR CELL) TYPE (9.0 CM), TUMOR EXTENDS INTO RENAL SINUS, LYMPHOVASCULAR INVASION BY TUMOR IS PRESENT; SOFT TISSUE RESECTION MARGIN FREE OF TUMOR. MULTI-FOCAL RENAL CELL CARCINOMA (SO-CALLED "SATELLITE TUMOR NODULES) INVOLVING RENAL CORTEX.

Renal artery segment, unremarkable.

Ureter segment, unremarkable.

RENAL VEIN SEGMENT:

RENAL CELL CARCINOMA THROMBUS EXTENDING TO RENAL VEIN RESECTION MARGIN.

ADRENAL GLAND:

METASTATIC RENAL CELL CARCINOMA.

GROSS DESCRIPTION

(A) LEFT KIDNEY ADRENAL WITH RENAL VEIN THROMBUS - A radical nephrectomy specimen (20.0 x 14.0 x 8.0 cm) includes: the tumor-distorted left kidney (15.0 x 10.0 x 5.5 cm); a segment of unremarkable renal artery; the tumor-distorted renal vein; segment of unremarkable ureter (4.0 cm in length and 0.3 cm average diameter); and the tumor-distorted adrenal gland (6.5 x 2.0 x 1.0 cm).

There is a 9.0 x 7.7 x 5.5 cm well circumscribed tumor in the mid pole of the kidney. The tumor is variegated, red-tan with extensive areas of, predominantly central hemorrhage and necrosis.. The tumor invades into the renal sinus and renal vein, and extends through a suprarenal vein into the adrenal gland. The tumor does not grossly extend to the Gerota's fascia.

There are multiple satellite nodules in the renal sinus and adjacent renal cortex. These satellite nodules may extent into the pelvic-calyceal system. No lymph nodes are identified in the hilum of the kidney.

Portions of the tumor have been submitted for possible electron microscopy as well as research protocols.

INK CODE:

Black: Gerota's fascia.

SECTION CODE:

A01, ureter, renal artery margin;

A02, renal vein margin with tumor thrombus;

A03-A06, adrenal with suprarenal vein tumor;

A07, tumor with adjacent normal kidney and satellite nodule;

[page 2 of 2]
A08, A09, tumor with Gerota's fascia;
A10, tumor with adjacent normal kidney;
A11, A12, satellite nodules in cortex;
A13, tumor and renal sinus;
A14, non-neoplastic kidney.

SNOMED CODES
T-71000, M-83123

Source: NCI Genomic Data Commons file 2fb9aacc-f096-4ae5-8fd4-99fd80ee345d (TCGA-CJ-5681.193BC4FF-FC27-4CF5-9220-1D21A27F29E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).